Somatic mutation profile of tumor specimen TARGET-30-PATPPU-01A (aliquot TARGET-30-PATPPU-01A-01D) from TARGET case TARGET-30-PATPPU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.9 years (1,049 days).
Specimen TARGET-30-PATPPU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc04ea3c-a62c-4d2d-aa75-599233e47ef5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATPPU-10A (Blood Derived Normal), aliquot TARGET-30-PATPPU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0667dee-c136-47a4-90fc-b167090b9a5f

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs138934947; called by muse, mutect2, varscan2
- CNTN5 | c.2115C>A p.N705K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV54291528, COSV54362945; called by muse, mutect2, varscan2
- KRAS | c.111+1G>T p.X37_splice | Splice Site (SNP) | VAF 10/113 reads (9%) | catalogued as COSV55883992; called by muse, mutect2
- MAML3 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RYR1 | c.12691G>T p.E4231* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- AHNAK | c.5320T>C p.L1774= | Silent (SNP) | VAF 36/436 reads (8%) | called by muse, mutect2
- FLT3 | c.2500C>A p.R834= | Silent (SNP) | VAF 85/183 reads (46%) | catalogued as COSV54043574, COSV54075066; called by muse, mutect2, varscan2
- MLLT1 | c.*2218G>A | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
